Somatic mutation profile of tumor specimen 0E1SC8 from CCDI case PBCWSV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1SC8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffe44aba-5e1a-4bf4-999f-887d8d005c62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1SBZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89d5aa19-3ae6-483f-9989-3fcf7ac694d7

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1597C>T p.R533C (on ENST00000399959; = p.R534C on NM_001356.5) | Missense Mutation (SNP) | VAF 180/203 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1555954284, COSV67863588, COSV67863748; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 140/320 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTCH1 | c.3158_3161dup p.I1055Rfs*91 | Frame Shift Ins (INS) | VAF 206/255 reads (81%) | called by mutect2, varscan2
- FGFR1 | c.1458G>A p.E486= (on ENST00000447712 / NM_023110.3; = p.E484= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 113/277 reads (41%) | called by muse, mutect2, varscan2
- DLEC1 | c.*163C>G | 3'UTR (SNP) | VAF 156/366 reads (43%) | called by mutect2, varscan2
